Somatic mutation profile of tumor specimen TCGA-EL-A4KG-01A (aliquot TCGA-EL-A4KG-01A-11D-A257-08) from TCGA case TCGA-EL-A4KG, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 35.5 years (12,978 days).
Specimen TCGA-EL-A4KG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f55567fd-145c-4ede-af57-9c780ab076c2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EL-A4KG-10A (Blood Derived Normal), aliquot TCGA-EL-A4KG-10A-01D-A25A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/660d269a-ca72-42ce-9d51-c76ebcc366a2

The open-access MAF lists 52 somatic variants for this specimen: 29 protein-altering or splice-affecting, 20 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 24, Silent 20, Nonsense Mutation 3, Splice Region 2, Intron 2, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- AACS | c.1374G>C p.E458D | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55535407, COSV55540987; called by muse, mutect2, varscan2
- ANKRD35 | c.103C>T p.R35C | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.289); catalogued as rs201747548; called by muse, mutect2, varscan2
- ATP11C | c.1372G>C p.D458H | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.139); catalogued as COSV59575876; called by muse, mutect2, varscan2
- BCL6 | c.1790C>G p.S597C | Missense Mutation (SNP) | VAF 19/89 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.665); catalogued as COSV51656247; called by muse, mutect2, varscan2
- CEP128 | c.1513G>C p.E505Q | Missense Mutation (SNP) | VAF 20/123 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.242); catalogued as COSV55392744; called by muse, varscan2
- CLBA1 | c.463C>T p.Q155* | Nonsense Mutation (SNP) | VAF 29/81 reads (36%) | catalogued as COSV66348629; called by muse, mutect2, varscan2
- DPP3 | c.1754G>C p.G585A | Missense Mutation (SNP) | VAF 30/83 reads (36%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.477); catalogued as COSV64756315, COSV64758245; called by muse, mutect2, varscan2
- DST | c.12511G>C p.D4171H (on ENST00000361203 / NM_001374722.1; = p.D1759H on NM_015548.5) | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.234); catalogued as COSV55044647; called by muse, mutect2, varscan2
- ELOVL1 | c.700C>T p.H234Y | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.027); catalogued as COSV60523256; called by muse, mutect2, varscan2
- EXT2 | c.627G>A p.R209= (on ENST00000343631; = p.R242= on NM_000401.3) | Splice Region (SNP) | VAF 8/120 reads (7%) | catalogued as COSV59156010; called by muse, mutect2
- FAT3 | c.7510G>A p.E2504K | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.758); catalogued as COSV53183030; called by muse, mutect2, varscan2
- GAK | c.3232C>T p.Q1078* | Nonsense Mutation (SNP) | VAF 22/92 reads (24%) | catalogued as COSV58510654; called by muse, mutect2, varscan2
- KMT2C | c.11541G>C p.K3847N | Missense Mutation (SNP) | VAF 28/127 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51305316; called by muse, mutect2, varscan2
- LAMC3 | c.2343G>C p.Q781H | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as COSV63093442; called by muse, mutect2
- LIPE | c.1422C>T p.F474= | Splice Region (SNP) | VAF 26/109 reads (24%) | catalogued as COSV54925045, COSV54926007; called by muse, mutect2, varscan2
- NCAPG2 | c.790G>C p.E264Q | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV51987718, COSV51992432; called by muse, mutect2, varscan2
- NDUFAF6 | c.286G>A p.E96K | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV54411211; called by muse, mutect2, varscan2
- NRP1 | c.1262T>C p.V421A | Missense Mutation (SNP) | VAF 42/116 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.713); catalogued as rs775349899, COSV55179011; called by muse, mutect2, varscan2
- P4HB | c.961G>C p.E321Q | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.83); catalogued as COSV58943124; called by muse, mutect2, varscan2
- RHOQ | c.409G>C p.D137H | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.924); catalogued as rs779078356, COSV53191215; called by muse, mutect2, varscan2
- RIOK2 | c.1004C>T p.S335L | Missense Mutation (SNP) | VAF 31/159 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as rs200897705, COSV51612856; called by muse, mutect2, varscan2
- RPTN | c.1649C>T p.T550I | Missense Mutation (SNP) | VAF 38/788 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs1384422232, COSV60169517; called by muse, mutect2
- RPTN | c.541C>T p.H181Y | Missense Mutation (SNP) | VAF 84/399 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.165); catalogued as COSV60169524; called by muse, mutect2, varscan2
- TBX18 | c.460G>A p.E154K | Missense Mutation (SNP) | VAF 26/130 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.9); catalogued as COSV63738513; called by muse, mutect2, varscan2
- TMEM47 | c.532G>T p.E178* | Nonsense Mutation (SNP) | VAF 19/72 reads (26%) | catalogued as COSV52068247; called by muse, mutect2, varscan2
- TMEM54 | c.148C>G p.Q50E | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT tolerated (0.6); PolyPhen benign (0.061); catalogued as COSV61276501; called by muse, mutect2, varscan2
- TRIM24 | c.2000C>T p.S667F (on ENST00000343526 / NM_015905.3; = p.S633F on NM_003852.4) | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV58979042; called by muse, mutect2, varscan2
- VTA1 | c.456C>G p.I152M | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62659507; called by muse, mutect2, varscan2
- ABCC12 | c.1671G>A p.V557= | Silent (SNP) | VAF 14/50 reads (28%) | catalogued as COSV60918853; called by muse, mutect2, varscan2
- AFAP1L2 | c.993C>G p.L331= | Silent (SNP) | VAF 7/52 reads (13%) | catalogued as COSV58419187; called by muse, mutect2, varscan2
- ANAPC15 | c.46C>T p.L16= | Silent (SNP) | VAF 24/110 reads (22%) | catalogued as rs868800752, COSV56193987; called by muse, mutect2, varscan2
- CHGB | c.1665G>A p.L555= | Silent (SNP) | VAF 20/78 reads (26%) | catalogued as COSV66762005; called by muse, mutect2, varscan2
- ETAA1 | c.2380T>C p.L794= | Silent (SNP) | VAF 20/53 reads (38%) | catalogued as rs758407178, COSV55475499; called by muse, mutect2, varscan2
- HECTD4 | c.2685G>A p.L895= | Silent (SNP) | VAF 4/17 reads (24%) | catalogued as COSV61181831; called by muse, mutect2, varscan2
- KDF1 | c.726C>A p.L242= | Silent (SNP) | VAF 9/45 reads (20%) | catalogued as COSV57672303; called by muse, mutect2, varscan2
- LMTK3 | c.666C>G p.L222= | Silent (SNP) | VAF 5/30 reads (17%) | catalogued as COSV54317853; called by muse, mutect2
- MST1 | c.735C>A p.L245= | Silent (SNP) | VAF 6/39 reads (15%) | catalogued as COSV56532395, COSV56537231; called by muse, mutect2
- MUC17 | c.13020C>A p.I4340= | Silent (SNP) | VAF 28/147 reads (19%) | catalogued as COSV60306355; called by muse, mutect2
- PGAP2 | c.462C>G p.L154= (on ENST00000463452 / NM_001346398.2; = p.L215= on NM_014489.4) | Silent (SNP) | VAF 25/93 reads (27%) | catalogued as rs559872012, COSV53467950; called by muse, mutect2, varscan2
- PHLDB2 | c.801G>A p.L267= | Silent (SNP) | VAF 18/58 reads (31%) | catalogued as COSV67316663; called by muse, mutect2, varscan2
- PI4KB | c.2412C>G p.L804= (on ENST00000368873 / NM_001369623.1; = p.L816= on NM_002651.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 16/68 reads (24%) | catalogued as COSV55022235; called by muse, mutect2, varscan2
- TAGAP | c.1164C>G p.L388= | Silent (SNP) | VAF 14/61 reads (23%) | catalogued as COSV57853405; called by muse, mutect2, varscan2
- TAS1R1 | c.1002G>A p.L334= | Silent (SNP) | VAF 12/38 reads (32%) | catalogued as COSV59840991; called by muse, mutect2, varscan2
- TAS1R3 | c.1996C>T p.L666= | Silent (SNP) | VAF 9/47 reads (19%) | catalogued as COSV59566368; called by muse, mutect2, varscan2
- TCF7L1 | c.912G>A p.G304= | Silent (SNP) | VAF 22/78 reads (28%) | catalogued as COSV56404061; called by muse, mutect2, varscan2
- TRPM3 | c.627C>G p.L209= (on ENST00000357533 / NM_001366142.2; = p.L54= on NM_020952.6) | Silent (SNP) | VAF 27/161 reads (17%) | catalogued as COSV62467965, COSV62472363, COSV62474844; called by muse, mutect2, varscan2
- TSSK2 | c.24G>A p.R8= | Silent (SNP) | VAF 10/44 reads (23%) | catalogued as COSV52818785; called by muse, mutect2, varscan2
- ZNF436 | c.1113C>T p.F371= | Silent (SNP) | VAF 18/78 reads (23%) | catalogued as COSV58359623; called by muse, mutect2, varscan2
- AKAP13 | c.4800-2133G>C | Intron (SNP) | VAF 29/114 reads (25%) | catalogued as COSV63471587; called by muse, mutect2, varscan2
- SERPINA9 | chr14:94476153 C>T | 5'Flank (SNP) | VAF 50/208 reads (24%) | catalogued as COSV54079095; called by muse, mutect2, varscan2
- THSD4 | c.-80+14415G>C | Intron (SNP) | VAF 6/18 reads (33%) | catalogued as COSV62504959; called by muse, mutect2, varscan2
